Somatic mutation profile of tumor specimen TCGA-55-8203-01A (aliquot TCGA-55-8203-01A-11D-2238-08) from TCGA case TCGA-55-8203, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.8 years (25,477 days).
Specimen TCGA-55-8203-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be74c31e-7e92-4d6e-b51f-147c08571e3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8203-10A (Blood Derived Normal), aliquot TCGA-55-8203-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/267967f3-55ab-4d6c-8fc0-967caeb246ff

The open-access MAF lists 464 somatic variants for this specimen: 353 protein-altering or splice-affecting, 102 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 102, Nonsense Mutation 18, Frame Shift Del 9, Splice Site 7, RNA 6, 3'UTR 1, Intron 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs772340371, COSV100588869; called by muse, mutect2, varscan2
- ABCA10 | c.3892A>G p.M1298V | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1344570287, COSV99289097; called by muse, mutect2, varscan2
- ABCA13 | c.2405G>A p.W802* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101330130; called by muse, mutect2, varscan2
- ABCB5 | c.3116G>T p.S1039I (on ENST00000404938 / NM_001163941.2; = p.S594I on NM_178559.6) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99329129; called by muse, mutect2, varscan2
- ABI3BP | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767968797, COSV52544937, COSV99428005; called by muse, mutect2, varscan2
- ABL2 | c.893A>T p.Q298L (on ENST00000502732 / NM_007314.4; = p.Q283L on NM_005158.5) | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100772898; called by muse, mutect2, varscan2
- AC004832.3 | c.953A>T p.D318V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1365317570, COSV99840937; called by muse, varscan2
- ADAM7 | c.2246C>A p.P749H | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV99444627; called by muse, mutect2, varscan2
- ADAMTS12 | c.4444C>A p.L1482M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV100711468, COSV61267351; called by muse, mutect2, varscan2
- ADAMTS12 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711469; called by muse, mutect2, varscan2
- ADARB2 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.993); catalogued as COSV101187126; called by muse, mutect2, varscan2
- ADGRG4 | c.4033T>C p.S1345P | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV99796248; called by muse, varscan2
- ADGRL1 | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV100529700; called by muse, mutect2, varscan2
- AEBP1 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV99788983; called by muse, mutect2, varscan2
- AFAP1L2 | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100412846; called by muse, mutect2, varscan2
- AFF2 | c.2249G>T p.C750F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV99665519; called by muse, mutect2, varscan2
- AGPS | c.1362+1G>T p.X454_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99931586; called by muse, mutect2
- AHCTF1 | c.944G>C p.R315P (on ENST00000366508; = p.R289P on NM_015446.5) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100404170; called by muse, mutect2, varscan2
- AMER1 | c.790G>C p.A264P | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.776); catalogued as COSV100366809; called by muse, mutect2, varscan2
- AMMECR1 | c.983C>A p.P328Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.603); catalogued as COSV99467006; called by muse, mutect2, varscan2
- AMMECR1 | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467008; called by muse, mutect2, varscan2
- ANGPT1 | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99863679; called by muse, mutect2, varscan2
- ANK3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs140324936, COSV55085351; called by muse, mutect2, varscan2
- APBB1IP | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV63304209; called by muse, mutect2, varscan2
- APOB | c.12373G>T p.D4125Y | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV51923261, COSV99267006; called by muse, mutect2, varscan2
- AQP10 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270380; called by muse, mutect2, varscan2
- ARFGAP2 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV100125615; called by muse, mutect2, varscan2
- ARHGAP15 | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.356); catalogued as COSV99712600; called by muse, mutect2, varscan2
- ARMCX2 | c.1512C>A p.H504Q | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100168239; called by muse, mutect2, varscan2
- ARR3 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100330925; called by mutect2, varscan2
- ATP13A4 | c.3126G>A p.W1042* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as COSV100710575; called by muse, mutect2, varscan2
- ATP1A2 | c.2813G>T p.R938L | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV100767806, COSV100768062; called by muse, mutect2, varscan2
- ATP2B2 | c.2071G>T p.V691L (on ENST00000352432; = p.V657L on NM_001683.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100660273, COSV59492940; called by muse, mutect2, varscan2
- ATP6V0C | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as rs779029141, COSV99566052; called by muse, mutect2, varscan2
- ATP8B4 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99466811; called by muse, mutect2, varscan2
- AXIN2 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100196803; called by muse, mutect2, varscan2
- BEND2 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1313086616, COSV101192137; called by muse, mutect2
- BRINP3 | c.2129T>G p.V710G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100819183; called by muse, mutect2, varscan2
- C11orf87 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100535866, COSV59357354, COSV59357587; called by muse, mutect2, varscan2
- C5orf46 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV100568461; called by muse, mutect2, varscan2
- CA6 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV66263315; called by muse, mutect2, varscan2
- CACNA1F | c.2136C>A p.D712E | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100545184; called by muse, mutect2, varscan2
- CARD9 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV100047549; called by muse, mutect2, varscan2
- CAVIN4 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.958); catalogued as COSV56867685; called by muse, mutect2, varscan2
- CCDC63 | c.1414G>C p.A472P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100370524; called by muse, mutect2, varscan2
- CCKBR | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100583050; called by muse, mutect2, varscan2
- CD163L1 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as COSV100550483, COSV58026418; called by muse, mutect2, varscan2
- CD200 | c.412C>A p.L138M (on ENST00000473539 / NM_001004196.3; = p.L113M on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.281); catalogued as COSV100238438, COSV59863533; called by muse, mutect2, varscan2
- CD22 | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323574; called by muse, mutect2, varscan2
- CD4 | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.038); catalogued as COSV99163851; called by muse, mutect2, varscan2
- CDH22 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952950; called by muse, mutect2, varscan2
- CDH7 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100542916, COSV59884052; called by muse, mutect2, varscan2
- CDH9 | c.1700C>A p.P567Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50284915; called by muse, mutect2, varscan2
- CDH9 | c.1699C>A p.P567T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770537311, COSV99142015, COSV99150769; called by muse, mutect2, varscan2
- CFAP47 | c.4789G>T p.V1597L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.827); catalogued as COSV100545604; called by muse, mutect2, varscan2
- CHSY3 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.13); catalogued as rs373484838, COSV59275330; called by muse, mutect2, varscan2
- CLEC3B | c.597C>A p.F199L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944617; called by muse, mutect2, varscan2
- CLEC4F | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99713915; called by muse, mutect2, varscan2
- CLMP | c.37T>A p.Y13N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101507430; called by muse, mutect2, varscan2
- CNTN4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.06); catalogued as COSV101281525; called by muse, mutect2, varscan2
- COL19A1 | c.3337C>A p.P1113T | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100507041; called by muse, mutect2, varscan2
- COL4A1 | c.4184C>A p.P1395Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as COSV101011390; called by muse, mutect2, varscan2
- COL5A1 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as COSV65668094, COSV65674250; called by muse, mutect2
- COL6A6 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100650676, COSV62022192; called by muse, mutect2
- COL9A3 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59653399; called by muse, mutect2, varscan2
- COL9A3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59652934; called by muse, mutect2, varscan2
- CPXCR1 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV52163158, COSV99342342; called by muse, mutect2, varscan2
- CR1 | c.6059G>A p.G2020D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.006); catalogued as COSV100887910; called by muse, mutect2, varscan2
- CR2 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as COSV100889569, COSV100889683; called by muse, mutect2, varscan2
- CRB1 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); catalogued as COSV100957898, COSV100958021; called by muse, mutect2, varscan2
- CSMD1 | c.5459C>A p.P1820H (on ENST00000520002; = p.P1819H on NM_033225.6) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151860; called by muse, mutect2
- CSMD1 | c.2254G>A p.V752M (on ENST00000520002; = p.V751M on NM_033225.6) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369449812; called by muse, mutect2, varscan2
- CSRP3 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99788347; called by muse, mutect2, varscan2
- CTNNA2 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100561623; called by muse, mutect2, varscan2
- CTNNA3 | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101050979; called by muse, mutect2, varscan2
- DCAF4L2 | c.780C>G p.S260R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60476418; called by muse, mutect2, varscan2
- DCLRE1C | c.166A>T p.K56* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100739937; called by muse, mutect2, varscan2
- DDX53 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100029040; called by muse, mutect2, varscan2
- DHRS2 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99159862; called by muse, mutect2, varscan2
- DIAPH2 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV61259810, COSV61276815; called by muse, mutect2
- DIDO1 | c.1470A>T p.E490D | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV99826618; called by muse, mutect2, varscan2
- DNAJB9 | c.610A>T p.R204W | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99974559; called by muse, mutect2, varscan2
- DONSON | c.651C>A p.S217R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs751861655, COSV99281102; called by muse, mutect2, varscan2
- DPP6 | c.337T>A p.S113T (on ENST00000377770 / NM_001364500.2; = p.S51T on NM_001936.5) | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100127163; called by muse, mutect2, varscan2
- DRD5 | c.853C>A p.R285S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs754629025, COSV100431959, COSV58577042, COSV58577153; called by muse, mutect2, varscan2
- DRP2 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100872000; called by muse, mutect2, varscan2
- DSG4 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100356225, COSV57389096; called by muse, mutect2, varscan2
- DST | c.3831G>T p.Q1277H (on ENST00000361203 / NM_001374722.1; = p.Q951H on NM_001723.6) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554214573, COSV99758607; called by muse, mutect2, varscan2
- DUSP29 | c.103A>T p.T35S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100633380; called by muse, mutect2, varscan2
- EOLA1 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs141148310, COSV100828433; called by muse, mutect2, varscan2
- EPHA6 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064799, COSV67574945; called by muse, mutect2, varscan2
- ERMN | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68075381; called by muse, mutect2, varscan2
- F2RL2 | c.1083G>C p.M361I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV56971697, COSV99167787; called by muse, mutect2, varscan2
- F2RL2 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99167788; called by muse, mutect2, varscan2
- F5 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100889194; called by muse, mutect2, varscan2
- F8 | c.5786C>A p.P1929H | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100811719; called by muse, mutect2, varscan2
- FAM160A2 | c.2628G>T p.Q876H (on ENST00000449352 / NM_001098794.2; = p.Q890H on NM_032127.4) | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV99792328; called by muse, mutect2, varscan2
- FAM167B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100405839; called by muse, mutect2
- FBN2 | c.8226del p.Q2743Sfs*52 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as COSV52548510; called by mutect2, pindel, varscan2
- FBN2 | c.6542T>G p.I2181S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99329531; called by muse, mutect2, varscan2
- FCRL5 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100709174; called by muse, mutect2, varscan2
- FGF13 | c.614A>T p.K205M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100264498; called by muse, mutect2, varscan2
- FIP1L1 | c.1637G>T p.S546I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99820338; called by muse, mutect2, varscan2
- FOXD4 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs772348861, COSV100071139; called by muse, mutect2, varscan2
- FREM2 | c.5736G>T p.Q1912H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99749972; called by muse, mutect2, varscan2
- FRMD6 | c.1514G>C p.G505A (on ENST00000344768 / NM_001267046.2; = p.G497A on NM_152330.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100656102; called by muse, mutect2, varscan2
- FUNDC2 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV101045597; called by muse, mutect2, varscan2
- GABBR1 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV100589915; called by muse, mutect2, varscan2
- GATA1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100936848; called by muse, mutect2, varscan2
- GCM2 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV101069587, COSV101069614; called by muse, mutect2, varscan2
- GJA8 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as COSV53788283; called by muse, mutect2, varscan2
- GLA | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960765, COSV99516511; called by muse, mutect2, varscan2
- GLE1 | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV100012735; called by muse, mutect2, varscan2
- GLUD2 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100047007, COSV100047088; called by muse, mutect2, varscan2
- GPR158 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV100894087; called by muse, mutect2, varscan2
- GPR174 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99338313; called by muse, mutect2, varscan2
- GPR35 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV100166610; called by muse, mutect2, varscan2
- GRIN2A | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58019525; called by muse, mutect2, varscan2
- GRIP2 | c.1361C>T p.P454L (on ENST00000619221; = p.P357L on NM_001080423.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1263788792, COSV99817532; called by muse, mutect2, varscan2
- GUCY2F | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99485431; called by muse, mutect2
- HAS2 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392072, COSV58263497; called by muse, mutect2, varscan2
- HCN1 | c.2312C>A p.T771K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); catalogued as COSV100299249, COSV100301532; called by muse, mutect2, varscan2
- HCN1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100301533, COSV57533867; called by muse, mutect2, varscan2
- HELB | c.2012G>T p.R671L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV56072497, COSV99922101; called by muse, mutect2, varscan2
- HERC2 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99875711; called by muse, mutect2, varscan2
- HGF | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV99737959; called by muse, mutect2, varscan2
- HID1 | c.1147A>T p.K383* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100586045; called by muse, mutect2, varscan2
- HTR1A | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100109215; called by muse, mutect2, varscan2
- HTR5A | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs764637143, COSV99839868; called by muse, mutect2, varscan2
- HYAL4 | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99772392; called by muse, mutect2, varscan2
- ICOS | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.104); catalogued as rs111644920, COSV100320399; called by mutect2, varscan2
- IFNG | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99971237; called by muse, mutect2, varscan2
- IL1RAPL2 | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV100781746; called by muse, mutect2, varscan2
- ISL1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs1435635029, COSV100045607, COSV57933430; called by muse, mutect2, varscan2
- ITGB7 | c.1397T>A p.L466Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99914196; called by muse, mutect2, varscan2
- KBTBD6 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101068837; called by muse, mutect2, varscan2
- KBTBD8 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV99805823; called by muse, mutect2, varscan2
- KCNS2 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.635); catalogued as rs942498856, COSV99751344; called by muse, mutect2, varscan2
- KDR | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV55765869, COSV99818320; called by muse, mutect2, varscan2
- KIAA1109 | c.8249A>T p.E2750V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99169333; called by muse, mutect2, varscan2
- KIAA1549 | c.4628G>T p.G1543V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651549, COSV99651823; called by muse, mutect2, varscan2
- KIAA1549L | c.2464C>A p.Q822K (on ENST00000321505; = p.Q1119K on NM_012194.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99684091; called by mutect2, varscan2
- KIF1B | c.2359-1G>T p.X787_splice (on ENST00000377086 / NM_001365952.1; = p.X741_splice on NM_015074.3) | Splice Site (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99823864; called by muse, mutect2, varscan2
- KIF4B | c.3298G>T p.G1100W | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101469367; called by muse, mutect2, varscan2
- KIF4B | c.3299G>T p.G1100V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV70528477; called by muse, mutect2, varscan2
- KRT2 | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100548592; called by muse, mutect2, varscan2
- LACTB2 | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV52569254, COSV99399577; called by muse, mutect2, varscan2
- LBR | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99687592; called by muse, mutect2, varscan2
- LECT2 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV99191893; called by muse, mutect2, varscan2
- LGSN | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV101040624; called by muse, mutect2, varscan2
- LHX5 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV99922525; called by muse, mutect2, varscan2
- LILRA6 | c.1360del p.A454Qfs*64 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as COSV54439913; called by mutect2, pindel, varscan2
- LILRB1 | c.1700T>A p.L567Q (on ENST00000427581; = p.L517Q on NM_006669.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100207639; called by muse, mutect2, varscan2
- LMNB2 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100322349; called by muse, mutect2, varscan2
- LRP1B | c.9854G>T p.S3285I | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101259058; called by muse, mutect2, varscan2
- LRP1B | c.5705C>G p.A1902G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV101259059; called by muse, mutect2, varscan2
- MAB21L2 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.141); catalogued as COSV100462346; called by muse, mutect2, varscan2
- MAGEC2 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99909745, COSV99909797; called by muse, mutect2
- MAP1S | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100141136; called by muse, mutect2, varscan2
- MARCHF1 | c.198C>A p.S66R (on ENST00000274056; = p.S49R on NM_017923.4) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV56834618; called by muse, mutect2, varscan2
- MARK3 | c.2131G>T p.V711L (on ENST00000429436 / NM_001128918.3; = p.V687L on NM_002376.6) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748756539, COSV99358225, COSV99358612; called by muse, mutect2, varscan2
- MAST2 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.44); catalogued as COSV100788001, COSV100788592; called by muse, mutect2, varscan2
- MBD5 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV101290203; called by muse, mutect2, varscan2
- MCF2 | c.2424G>T p.L808F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644979; called by muse, mutect2, varscan2
- MEGF8 | c.5780G>A p.R1927H (on ENST00000251268 / NM_001271938.2; = p.R1860H on NM_001410.3) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs559115816, COSV52073904; called by muse, mutect2, varscan2
- MIA2 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV99696867; called by muse, mutect2, varscan2
- MMP16 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV99689680; called by muse, mutect2, varscan2
- MMRN1 | c.2764A>G p.K922E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs928725203, COSV99307503; called by muse, mutect2, varscan2
- MTR | c.2573T>A p.I858N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855480; called by muse, mutect2, varscan2
- MUC16 | c.5909C>A p.P1970Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101200652; called by muse, mutect2, varscan2
- MXRA5 | c.2963C>A p.P988Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV99478400; called by muse, mutect2, varscan2
- MYH2 | c.4934C>A p.A1645D | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99820648; called by muse, mutect2, varscan2
- MYH3 | c.4991G>T p.G1664V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.152); catalogued as COSV99878615; called by muse, mutect2, varscan2
- MYH8 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238579; called by muse, mutect2, varscan2
- MYO10 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.065); catalogued as COSV101569832; called by muse, mutect2, varscan2
- MYO18A | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100572530; called by muse, mutect2, varscan2
- NAV3 | c.3524C>A p.T1175N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV99893928; called by muse, mutect2, varscan2
- NCAM2 | c.2462T>C p.I821T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as COSV99524454; called by muse, mutect2, varscan2
- NEB | c.9859C>G p.Q3287E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV99425950; called by muse, mutect2, varscan2
- NELL1 | c.1839C>A p.C613* | Nonsense Mutation (SNP) | VAF 47/197 reads (24%) | catalogued as COSV100123508; called by muse, mutect2, varscan2
- NKRF | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100441812; called by muse, mutect2, varscan2
- NLRP14 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100205282; called by muse, mutect2, varscan2
- NOL11 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475221; called by muse, mutect2, varscan2
- NRDE2 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV100583594; called by muse, mutect2, varscan2
- NRG1 | c.569G>T p.C190F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99828994; called by muse, mutect2, varscan2
- NXF3 | c.1245C>A p.H415Q | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV101222041; called by muse, mutect2, varscan2
- OBSCN | c.8846G>T p.R2949L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs201038562, COSV99482262; called by muse, mutect2, varscan2
- OCA2 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100668336; called by muse, mutect2, varscan2
- OR2AE1 | c.775A>T p.M259L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as rs766641784, COSV100318337; called by muse, mutect2, varscan2
- OR2G2 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100189864, COSV60742602; called by muse, mutect2
- OR2G6 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100598274; called by muse, mutect2, varscan2
- OR2L13 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100813858; called by muse, mutect2, varscan2
- OR4A47 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101487083; called by muse, mutect2, varscan2
- OR4C6 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs146965889, COSV100051763; called by muse, mutect2, varscan2
- OR52L1 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176282; called by muse, mutect2, varscan2
- OR56A4 | c.528C>G p.D176E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100417650; called by muse, mutect2, varscan2
- OR5B21 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV100835166, COSV64481932; called by muse, mutect2, varscan2
- OR6F1 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100129363; called by muse, mutect2, varscan2
- OTOF | c.2246T>A p.I749N (on ENST00000272371 / NM_194248.3; = p.I2N on NM_004802.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs372085440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PABPC5 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100442607; called by muse, mutect2
- PAMR1 | c.1726G>T p.V576F (on ENST00000619888 / NM_001001991.3; = p.V593F on NM_015430.4) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99552996; called by muse, mutect2, varscan2
- PANK4 | c.1705T>G p.W569G | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65868010; called by muse, mutect2, varscan2
- PCDH17 | c.3294G>T p.R1098S | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); catalogued as COSV64974118; called by muse, mutect2, varscan2
- PCDH7 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688543; called by muse, mutect2, varscan2
- PCDH9 | c.3316G>T p.D1106Y (on ENST00000377865 / NM_203487.3; = p.D1072Y on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122474; called by muse, mutect2, varscan2
- PCDHA3 | c.2135T>A p.V712E | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100793630; called by muse, mutect2, varscan2
- PDILT | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV99043626; called by muse, mutect2, varscan2
- PHLPP1 | c.4502G>C p.G1501A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.041); catalogued as COSV99408888; called by muse, mutect2
- PITPNC1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100083919; called by muse, mutect2, varscan2
- PKD1L1 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV99220888; called by muse, mutect2, varscan2
- PKHD1 | c.3344G>A p.R1115K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV100584055; called by muse, mutect2, varscan2
- PLAC8 | c.145T>A p.C49S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100274555; called by muse, mutect2, varscan2
- PLCE1 | c.1926C>A p.N642K | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596310; called by muse, mutect2
- PLK4 | c.548C>G p.A183G | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99584841; called by muse, mutect2, varscan2
- PLPPR4 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs757156058, COSV100926876; called by muse, mutect2, varscan2
- POF1B | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53136076, COSV99426410, COSV99427158; called by muse, mutect2, varscan2
- PPP1R26 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV100778128; called by muse, mutect2, varscan2
- PPP1R3A | c.3117C>A p.Y1039* | Nonsense Mutation (SNP) | VAF 66/234 reads (28%) | catalogued as COSV99493723; called by muse, mutect2, varscan2
- PPP1R3A | c.2324C>G p.P775R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52889819, COSV99493725; called by muse, mutect2, varscan2
- PPP2R1A | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100436395; called by muse, mutect2, varscan2
- PRKACA | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as COSV100432173, COSV100432191; called by muse, mutect2, varscan2
- PROS1 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101260730; called by muse, mutect2
- PRRC2A | c.4430A>G p.Q1477R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101051303; called by mutect2, varscan2
- PSMA7 | c.348+1G>A p.X116_splice | Splice Site (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99444575; called by muse, mutect2, varscan2
- PTER | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100126774, COSV54346811; called by muse, mutect2, varscan2
- PTPN2 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518684; called by muse, mutect2, varscan2
- PTPRB | c.201G>T p.L67F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as COSV99718396; called by mutect2, varscan2
- PTPRH | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 43/278 reads (15%) | catalogued as COSV99671303; called by muse, mutect2, varscan2
- PTPRO | c.2766C>G p.D922E (on ENST00000281171 / NM_030667.3; = p.D894E on NM_002848.4) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV99841332; called by muse, mutect2, varscan2
- R3HDM1 | c.2764G>T p.V922F | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as rs370032006; called by muse, mutect2, varscan2
- RABGAP1 | c.2916C>G p.C972W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101017081; called by muse, mutect2, varscan2
- RASAL2 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100862756; called by muse, mutect2, varscan2
- RBFOX1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV100302832, COSV60988814; called by muse, mutect2, varscan2
- RBMXL2 | c.739A>T p.S247C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100182414; called by muse, mutect2, varscan2
- RETSAT | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99806161; called by muse, mutect2, varscan2
- RIMS2 | c.1641C>G p.N547K (on ENST00000666250 / NM_001348490.2; = p.N355K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as COSV99179901; called by muse, mutect2, varscan2
- RNF121 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100683638; called by muse, mutect2, varscan2
- RP1 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99608353; called by muse, mutect2, varscan2
- RPTN | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV100285654; called by muse, mutect2
- RSPH1 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs753686273, COSV99370611; called by muse, mutect2, varscan2
- RSPH14 | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99321015, COSV99321057; called by muse, mutect2, varscan2
- RYR2 | c.5701C>A p.P1901T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV63705805; called by muse, mutect2, varscan2
- RYR3 | c.1971C>A p.Y657* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV101213513; called by muse, mutect2, varscan2
- RYR3 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV101212767; called by muse, mutect2, varscan2
- SAXO1 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1316577267, COSV101000191; called by muse, mutect2, varscan2
- SAXO2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100255847, COSV59754219; called by muse, mutect2, varscan2
- SELP | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV55255026; called by muse, mutect2, varscan2
- SEMA4C | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100561107; called by muse, mutect2, varscan2
- SEPTIN5 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100820446; called by muse, mutect2, varscan2
- SGCZ | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 231/862 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV66034160; called by muse, mutect2, varscan2
- SH3BP2 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100697007; called by muse, mutect2, varscan2
- SHCBP1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100317457, COSV57648366; called by muse, mutect2, varscan2
- SLC12A2 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99321404; called by muse, varscan2
- SLC12A5 | c.236C>A p.P79H (on ENST00000454036 / NM_001134771.2; = p.P56H on NM_020708.5) | Missense Mutation (SNP) | VAF 93/390 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99716527; called by muse, mutect2, varscan2
- SLC14A2 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675923; called by muse, mutect2, varscan2
- SLC16A14 | c.328A>T p.N110Y | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99725769; called by muse, mutect2, varscan2
- SLC24A2 | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as COSV53864395; called by muse, mutect2, varscan2
- SLC2A5 | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs755633515, COSV101072679; called by muse, mutect2, varscan2
- SLC2A5 | c.347T>G p.M116R | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101072680; called by muse, mutect2, varscan2
- SLC38A7 | c.773A>T p.H258L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99543873; called by muse, mutect2, varscan2
- SLC66A3 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV99706344; called by muse, mutect2, varscan2
- SLITRK4 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100567447; called by muse, mutect2, varscan2
- SLITRK6 | c.1529C>A p.T510N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV68391392; called by muse, mutect2, varscan2
- SMAD4 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61694575; called by muse, mutect2, varscan2
- SMARCA1 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.209); catalogued as COSV100946260; called by muse, mutect2
- SMARCC1 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99593245; called by muse, mutect2, varscan2
- SORCS3 | c.2868+1G>T p.X956_splice | Splice Site (SNP) | VAF 58/246 reads (24%) | catalogued as COSV63794225; called by muse, mutect2, varscan2
- SPATA31D1 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as rs1265790392, COSV100782940; called by muse, mutect2, varscan2
- SPOP | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100753509; called by muse, mutect2, varscan2
- SPTBN4 | c.3812T>C p.I1271T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100151689; called by muse, mutect2, varscan2
- SPTBN5 | c.5151G>T p.E1717D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100311935; called by muse, mutect2, varscan2
- SRBD1 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99765376; called by muse, mutect2, varscan2
- STARD13 | c.633G>T p.Q211H (on ENST00000336934 / NM_001243476.3; = p.Q93H on NM_052851.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99716220; called by muse, mutect2, varscan2
- STK11 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58823539; called by muse, mutect2, varscan2
- STRA6 | c.1618A>T p.N540Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99997471; called by muse, mutect2, varscan2
- STXBP5L | c.2029G>T p.G677W | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99875606; called by muse, mutect2, varscan2
- SUCLA2 | c.911A>G p.Y304C (on ENST00000643023; = p.Y283C on NM_003850.3) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101074914; called by muse, mutect2, varscan2
- SYNE2 | c.2768G>T p.C923F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV100648221; called by muse, mutect2, varscan2
- SYNE3 | c.2903G>T p.R968L | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759211520, COSV100516328, COSV62081498; called by muse, mutect2, varscan2
- SYNPO2 | c.2639A>T p.Q880L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100206176; called by muse, mutect2, varscan2
- SYT1 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99696751; called by muse, mutect2, varscan2
- SYT1 | c.622A>C p.N208H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696753; called by muse, mutect2, varscan2
- TAS2R46 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs772925942, COSV101115286; called by muse, mutect2, varscan2
- TAZ | c.733G>C p.A245P | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as COSV100173378; called by muse, mutect2, varscan2
- TBR1 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV101271512; called by muse, mutect2, varscan2
- TBX22 | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV100960895; called by muse, mutect2, varscan2
- TECTA | c.1345G>T p.V449F | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV50770021, COSV99880933; called by muse, mutect2, varscan2
- TENM2 | c.797C>A p.S266Y (on ENST00000518659 / NM_001122679.2; = p.S75Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV101319269; called by muse, mutect2, varscan2
- TET2 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV54409708, COSV99484079; called by muse, mutect2, varscan2
- TGM4 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369266664; called by muse, mutect2, varscan2
- THADA | c.4400C>T p.T1467I | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1288189314, COSV100369235; called by muse, mutect2, varscan2
- TIGIT | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101048259; called by muse, mutect2, varscan2
- TLE1 | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100916338; called by muse, mutect2, varscan2
- TLR3 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV99711123; called by muse, mutect2, varscan2
- TLR4 | c.1861C>A p.L621M (on ENST00000355622 / NM_138554.5; = p.L581M on NM_003266.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as COSV62922689; called by muse, mutect2, varscan2
- TNXB | c.12227G>A p.R4076Q (on ENST00000647633; = p.R3829Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs889575324, COSV100926494; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1597A>T p.R533* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV99621541; called by muse, mutect2, varscan2
- TRIM48 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV101338333; called by muse, mutect2, varscan2
- TRPM4 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99420578; called by muse, varscan2
- TRPM8 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100224367; called by muse, mutect2, varscan2
- TRRAP | c.3574A>G p.M1192V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV100722740; called by muse, mutect2, varscan2
- TSHZ3 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs566625027, COSV53667537, COSV99552276; called by muse, mutect2, varscan2
- TST | c.596-1G>T p.X199_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99968224; called by muse, mutect2, varscan2
- TTC17 | c.3079G>T p.V1027L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99235740; called by muse, mutect2, varscan2
- TTF1 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100524816; called by muse, mutect2, varscan2
- TTI1 | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100989707; called by mutect2, varscan2
- TTN | c.67768G>T p.V22590L (on ENST00000591111; = p.V15166L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | PolyPhen benign (0.341); catalogued as COSV100623221; called by muse, mutect2, varscan2
- TTN | c.62879C>T p.S20960L (on ENST00000591111; = p.S13536L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/198 reads (19%) | PolyPhen benign (0.073); catalogued as COSV60208249; called by muse, mutect2, varscan2
- TTN | c.33241G>T p.V11081F (on ENST00000591111; = p.V10154F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | PolyPhen benign (0); catalogued as rs551911856, COSV100623225; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.29631A>T p.R9877S (on ENST00000591111; = p.R8950S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/138 reads (41%) | PolyPhen benign (0.124); catalogued as COSV100623226; called by muse, mutect2, varscan2
- UBE2A | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV100660522; called by muse, mutect2
- UGT3A1 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV99955121; called by muse, mutect2, varscan2
- ULK2 | c.1313G>T p.R438M | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV100860925; called by muse, mutect2, varscan2
- UNC5A | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1039635322, COSV99994919; called by muse, mutect2, varscan2
- UNC5CL | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV55110916, COSV99770927; called by muse, mutect2, varscan2
- UPP2 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99135136; called by muse, mutect2
- USP6 | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as rs373484514, COSV100004575; called by muse, mutect2, varscan2
- VCAM1 | c.1726G>T p.V576F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV99658795; called by muse, mutect2, varscan2
- VGLL1 | c.328A>T p.M110L | Missense Mutation (SNP) | VAF 259/594 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101034696; called by muse, mutect2, varscan2
- VN1R2 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV59037641; called by muse, varscan2
- VN1R4 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100237507; called by muse, mutect2, varscan2
- WNT7A | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV99541565; called by muse, mutect2, varscan2
- WNT9A | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV55293817, COSV99688378; called by mutect2, varscan2
- ZFP28 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100019759; called by muse, mutect2, varscan2
- ZFYVE26 | c.4355G>A p.S1452N | Missense Mutation (SNP) | VAF 150/540 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100720648; called by muse, mutect2
- ZNF536 | c.3237G>A p.M1079I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1568542526, COSV100834872, COSV100835585; called by muse, mutect2, varscan2
- ZNF597 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV100072074; called by muse, mutect2, varscan2
- ZNF608 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as COSV100102215; called by muse, mutect2, varscan2
- ZNF615 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100943903; called by muse, mutect2, varscan2
- ZNF75D | c.1054A>G p.M352V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1236143767, COSV100883679; called by muse, mutect2, varscan2
- ZNF804A | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV100169348; called by muse, mutect2, varscan2
- ZP4 | c.1311+2T>A p.X437_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100850744; called by muse, mutect2, varscan2
- ZP4 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100850745; called by muse, mutect2, varscan2
- CHRM1 | c.421del p.R141Gfs*4 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- GAREM1 | c.652_664del p.R218Efs*26 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- GIMAP5 | c.225del p.R76Gfs*42 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- HEMGN | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- IGBP1P2 | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV3-15 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 32/158 reads (20%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- LIN7A | c.159del p.V56Cfs*21 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- LRP1B | c.11775del p.M3926Wfs*9 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | called by mutect2, pindel, varscan2
- MUC16 | c.40625G>T p.G13542V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT12 | c.894dup p.K299* | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- OR4A5 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRAMEF19 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RYR2 | c.10240del p.R3414Efs*39 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- SLC8A1 | c.2470del p.H824Tfs*8 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.1948G>T p.G650C | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TRAJ31 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- TRAV1-1 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF232 | c.993_994del p.Y331* | Nonsense Mutation (DEL) | VAF 22/146 reads (15%) | called by pindel, varscan2
- ABCB1 | c.903T>C p.A301= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV99713819; called by muse, mutect2, varscan2
- ABCC1 | c.3843A>T p.T1281= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100580067; called by muse, mutect2, varscan2
- ADAP2 | c.990C>T p.L330= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs768129946, COSV100437329; called by muse, mutect2, varscan2
- ADGRB3 | c.4215A>T p.S1405= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV99486348; called by muse, mutect2, varscan2
- ADGRG4 | c.1413T>A p.P471= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV54956191; called by muse, mutect2
- AHSG | c.463C>T p.L155= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV99890226; called by muse, mutect2, varscan2
- ARPP21 | c.1320T>C p.A440= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV99492572; called by muse, mutect2, varscan2
- ATP5MC2 | c.261T>G p.S87= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV100101030; called by muse, mutect2, varscan2
- AVPR1A | c.120C>T p.G40= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs1460730957, COSV100146888; called by muse, mutect2, varscan2
- BCLAF1 | c.507T>A p.A169= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV100786824; called by muse, varscan2
- BGN | c.966C>A p.P322= | Silent (SNP) | VAF 29/283 reads (10%) | catalogued as COSV100525256; called by muse, mutect2, varscan2
- C1orf194 | c.219C>T p.D73= (on ENST00000369948 / NM_001245025.3; = p.D61= on NM_001122961.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV100885183; called by muse, mutect2, varscan2
- CACNA1G | c.4050C>T p.D1350= | Silent (SNP) | VAF 7/200 reads (4%) | catalogued as rs1232409306, COSV100662260; called by muse, mutect2
- CAVIN4 | c.396G>C p.V132= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100293342; called by muse, mutect2, varscan2
- CDH18 | c.1230T>A p.P410= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV99937175; called by muse, mutect2, varscan2
- CENPT | c.1173C>T p.A391= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99535289; called by muse, mutect2, varscan2
- CHL1 | c.765G>A p.G255= (on ENST00000397491 / NM_001253387.1; = p.G271= on NM_006614.4) | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV99851864; called by muse, mutect2, varscan2
- CNR1 | c.870C>T p.I290= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV62986580; called by muse, mutect2, varscan2
- COBL | c.2340G>C p.L780= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99473562; called by muse, mutect2, varscan2
- COL23A1 | c.552G>T p.G184= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101179467; called by muse, mutect2, varscan2
- CPZ | c.1683C>A p.V561= (on ENST00000360986 / NM_001014447.3; = p.V550= on NM_003652.3) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100249148; called by muse, mutect2, varscan2
- CSMD1 | c.10572T>A p.A3524= (on ENST00000520002; = p.A3523= on NM_033225.6) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100151856; called by muse, mutect2, varscan2
- DACH1 | c.1737G>T p.P579= (on ENST00000619232 / NM_001366712.1; = p.P325= on NM_004392.6) | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as rs370706409, COSV57512761; called by muse, mutect2, varscan2
- DACH2 | c.70C>A p.R24= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100913682; called by mutect2, varscan2
- DACH2 | c.318G>A p.L106= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100913683; called by muse, mutect2, varscan2
- DCAF12L1 | c.1128C>T p.D376= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100948392; called by muse, mutect2, varscan2
- DCAF12L2 | c.919C>A p.R307= | Silent (SNP) | VAF 111/306 reads (36%) | catalogued as COSV63582223, COSV63583649; called by muse, mutect2, varscan2
- DLK1 | c.1005C>A p.S335= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV100375361; called by muse, mutect2, varscan2
- DOP1A | c.702A>T p.S234= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99382593; called by muse, mutect2, varscan2
- ELF4 | c.429C>A p.A143= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV100257522; called by muse, mutect2
- FASLG | c.417A>G p.E139= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs780093284, COSV100390566; called by muse, mutect2, varscan2
- FBN2 | c.4929C>A p.P1643= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99329536; called by muse, mutect2, varscan2
- FXYD5 | c.427C>A p.R143= | Silent (SNP) | VAF 97/430 reads (23%) | catalogued as rs200435409, COSV100732733, COSV61569100; called by muse, mutect2, varscan2
- GRAMD1A | c.168G>T p.G56= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100526328; called by muse, mutect2, varscan2
- GREM2 | c.73C>A p.R25= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1377063510, COSV100547888, COSV58956914; called by muse, mutect2, varscan2
- GRID2 | c.2475C>A p.A825= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99939127; called by muse, mutect2, varscan2
- GRIN2A | c.3372G>A p.K1124= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs997535780, COSV58026188, COSV58051915; called by muse, mutect2, varscan2
- GRM1 | c.1609C>A p.R537= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99268075; called by muse, mutect2, varscan2
- GSG1 | c.54G>A p.E18= (on ENST00000651961 / NM_001080555.4; = p.E5= on NM_031289.5) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1174831003, COSV100189413; called by muse, mutect2, varscan2
- HAPLN3 | c.582G>T p.V194= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100613836; called by muse, mutect2, varscan2
- HOXA13 | c.744C>T p.G248= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs372907690, COSV99763657; called by mutect2, varscan2
- IDS | c.165G>T p.G55= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100558119; called by muse, mutect2, varscan2
- IFI16 | c.2172A>T p.T724= (on ENST00000295809 / NM_001364867.2; = p.T668= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV99857964; called by muse, mutect2, varscan2
- KCNC4 | c.1548G>T p.R516= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100873668; called by muse, mutect2, varscan2
- KDM5C | c.1984C>T p.L662= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100949371; called by muse, mutect2, varscan2
- KEL | c.1230C>T p.C410= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs765248382, COSV100787238; called by muse, mutect2, varscan2
- KIF4A | c.2886A>T p.T962= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100979605; called by muse, mutect2, varscan2
- KRTAP5-7 | c.36C>T p.S12= | Silent (SNP) | VAF 45/291 reads (15%) | catalogued as rs758672225, COSV101273236; called by muse, mutect2, varscan2
- LCLAT1 | c.189G>T p.L63= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV100093025; called by muse, mutect2, varscan2
- LHX2 | c.1194A>G p.S398= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV101010077; called by muse, mutect2, varscan2
- LLGL2 | c.21A>T p.P7= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99390234; called by muse, mutect2, varscan2
- LRP1B | c.3498C>T p.G1166= | Silent (SNP) | VAF 81/397 reads (20%) | catalogued as rs762752944, COSV67226743; called by muse, mutect2, varscan2
- LRRC30 | c.444G>A p.S148= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV101274390; called by muse, mutect2, varscan2
- MAGEB6B | c.870G>C p.S290= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- MAP1LC3C | c.156G>T p.P52= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs772410954, COSV100606518; called by muse, mutect2, varscan2
- MAP3K2 | c.1467C>A p.I489= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100789371, COSV61294189; called by muse, mutect2, varscan2
- MAP7D3 | c.966C>A p.S322= | Silent (SNP) | VAF 39/429 reads (9%) | catalogued as COSV100286558; called by muse, mutect2
- MDH2 | c.597C>T p.G199= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV100242773; called by muse, mutect2, varscan2
- MEGF8 | c.6570C>T p.N2190= (on ENST00000251268 / NM_001271938.2; = p.N2123= on NM_001410.3) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs767893103, COSV99238153; called by muse, mutect2, varscan2
- MID1 | c.963G>A p.K321= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100452637; called by muse, mutect2, varscan2
- MMP9 | c.1401C>G p.V467= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV100812439; called by muse, mutect2, varscan2
- MRRF | c.378G>T p.G126= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99939003; called by muse, varscan2
- MYO16 | c.987C>A p.P329= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV99194301; called by muse, mutect2, varscan2
- NAT9 | c.378C>T p.L126= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs151031640; called by muse, mutect2, varscan2
- NEFM | c.1917C>A p.G639= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV99647474; called by muse, mutect2, varscan2
- NEUROD1 | c.157C>T p.L53= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99717014; called by muse, mutect2, varscan2
- NLRP10 | c.576C>A p.T192= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs138681119, COSV100149868; called by muse, varscan2
- OR1D2 | c.687C>G p.P229= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100513946, COSV58921389; called by muse, mutect2, varscan2
- PADI6 | c.1830G>A p.A610= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs377677170; called by muse, mutect2
- PAPLN | c.1506G>T p.S502= (on ENST00000554301; = p.S475= on NM_173462.4) | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99389750; called by muse, mutect2, varscan2
- PAX1 | c.786C>G p.P262= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101270353; called by muse, mutect2, varscan2
- PCDH15 | c.1947A>T p.T649= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100225254; called by muse, mutect2, varscan2
- PDE4A | c.2544C>G p.A848= (on ENST00000380702 / NM_001111307.2; = p.A609= on NM_006202.3) | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99534833; called by muse, mutect2, varscan2
- PDE6A | c.1413C>A p.T471= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs778478114, COSV99678547; called by muse, mutect2, varscan2
- PIK3R1 | c.2148C>T p.Y716= (on ENST00000521381 / NM_181523.3; = p.Y446= on NM_181504.4) | Silent (SNP) | VAF 107/302 reads (35%) | catalogued as COSV99149031; called by muse, mutect2, varscan2
- PILRA | c.402A>T p.S134= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV99546653; called by muse, mutect2, varscan2
- PLA2G5 | c.348C>T p.Y116= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100908264; called by muse, mutect2, varscan2
- PPP1R26 | c.639G>T p.P213= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV100778127; called by muse, mutect2, varscan2
- PRDM9 | c.2268C>A p.G756= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as COSV57006604; called by muse, varscan2
- PSG1 | c.658C>A p.R220= | Silent (SNP) | VAF 69/468 reads (15%) | catalogued as COSV99740969; called by muse, mutect2, varscan2
- PTCH1 | c.1326G>T p.V442= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100109470, COSV59461792; called by muse, mutect2, varscan2
- PTPRC | c.3429C>A p.V1143= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100722910, COSV61414617; called by muse, mutect2, varscan2
- PWWP3B | c.507A>G p.S169= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100531496; called by muse, mutect2, varscan2
- RAB19 | c.423G>T p.L141= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV99325188; called by muse, mutect2, varscan2
- RELN | c.6147G>C p.A2049= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100634418, COSV58985680; called by muse, mutect2, varscan2
- RYR2 | c.6321G>T p.T2107= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100772088, COSV63684440; called by muse, mutect2, varscan2
- SCEL | c.73C>A p.R25= | Silent (SNP) | VAF 55/194 reads (28%) | catalogued as COSV100583101; called by muse, mutect2, varscan2
- SCN5A | c.2886C>A p.A962= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100348281, COSV100349807; called by muse, mutect2
- SEMA7A | c.969T>A p.G323= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs768616073, COSV99984932; called by muse, mutect2
- SLC22A12 | c.483T>A p.A161= | Silent (SNP) | VAF 58/157 reads (37%) | catalogued as COSV100327770; called by muse, mutect2, varscan2
- SLC26A2 | c.1026A>T p.A342= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99640302; called by muse, mutect2, varscan2
- SV2A | c.78G>T p.A26= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100975230; called by muse, mutect2, varscan2
- TENM2 | c.5634C>A p.R1878= (on ENST00000518659 / NM_001122679.2; = p.R1639= on NM_001080428.3) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV101319272; called by muse, mutect2, varscan2
- THBS2 | c.369G>C p.T123= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100827997, COSV64678338; called by muse, mutect2, varscan2
- TSSK1B | c.27A>T p.R9= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV101181148; called by muse, mutect2, varscan2
- UNC5A | c.768G>T p.L256= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99994914; called by muse, mutect2, varscan2
- VGLL1 | c.327C>A p.P109= | Silent (SNP) | VAF 260/597 reads (44%) | catalogued as COSV101034695; called by muse, mutect2, varscan2
- ZMYM3 | c.2133G>A p.L711= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs1232731308, COSV100078202; called by muse, mutect2, varscan2
- ZNF280B | c.897G>T p.P299= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100840404; called by muse, mutect2, varscan2
- ZNF343 | c.1215G>T p.G405= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99601563; called by muse, mutect2, varscan2
- ZNF417 | c.1518G>C p.A506= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100364359, COSV100364364; called by muse, mutect2, varscan2
- ZNF462 | c.3495C>T p.G1165= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99472825; called by muse, mutect2, varscan2
- ADGRE4P | n.184G>T | RNA (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826717 C>G | 3'Flank (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- EI24P4 | n.915C>A | RNA (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- NXF5 | n.554C>A | RNA (SNP) | VAF 64/195 reads (33%) | catalogued as rs762104778, COSV99534553; called by muse, mutect2, varscan2
- SRSF10 | c.*3429A>T | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.9181C>T | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100947802; called by muse, mutect2
- SSPOP | n.14244dup | RNA (INS) | VAF 4/10 reads (40%) | catalogued as rs760535412; called by mutect2, varscan2
- TTN | c.10361-4304C>T | Intron (SNP) | VAF 17/54 reads (31%) | catalogued as COSV60090122; called by muse, mutect2, varscan2
- XIST | n.8175C>A | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
